Somatic mutation profile of tumor specimen ALCH-AEQE-TTP1-A (aliquot ALCH-AEQE-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEQE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.3 years (28,248 days).
Specimen ALCH-AEQE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44ea1ac5-4cf4-4e0a-8044-7aad766a7e7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEQE-NB1-A (Blood Derived Normal), aliquot ALCH-AEQE-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70cbf45-5ec3-42e2-8170-d2d603c55319

The open-access MAF lists 436 somatic variants for this specimen: 289 protein-altering or splice-affecting, 94 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 94, Nonsense Mutation 27, Intron 25, 3'UTR 9, 5'UTR 7, RNA 7, Splice Site 6, 5'Flank 4, Frame Shift Del 4, Splice Region 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/449 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAAF3 | c.997del p.D333Tfs*75 (on ENST00000524407 / NM_001256715.2; = p.D380Tfs*75 on NM_178837.4) | Frame Shift Del (DEL) | VAF 114/375 reads (30%) | catalogued as rs756430359; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 117/475 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs373197517; called by muse, mutect2, varscan2
- AHNAK2 | c.7126G>A p.E2376K | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as rs772030469; called by muse, mutect2
- AKR1B1 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1379579977; called by muse, mutect2, varscan2
- AMER3 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58466480, COSV58466498; called by muse, mutect2, varscan2
- ARRDC4 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754568128; called by muse, varscan2
- ASTN1 | c.2618C>G p.P873R | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99922649; called by muse, mutect2, varscan2
- BLOC1S4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100296599; called by muse, mutect2, varscan2
- BPIFB2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV50072128; called by muse, mutect2, varscan2
- BTK | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 206/812 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58124575; called by muse, varscan2
- C6orf58 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV100314935, COSV61666808; called by muse, mutect2, varscan2
- CA9 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1267936105; called by muse, mutect2, varscan2
- CACNA1S | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs140246559; called by muse, mutect2, varscan2
- CCDC15 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 25/570 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as rs1268736590; called by muse, mutect2
- CDK18 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs1030180970; called by muse, mutect2, varscan2
- CFHR5 | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 66/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56824533; called by muse, mutect2, varscan2
- COL28A1 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778177213, COSV68084055; called by muse, mutect2, varscan2
- COX7B2 | c.61A>T p.S21C | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV57224506; called by muse, mutect2, varscan2
- CTNNA2 | c.1386C>T p.V462= | Splice Region (SNP) | VAF 18/110 reads (16%) | catalogued as COSV58141777; called by muse, varscan2
- CTNND2 | c.3371A>G p.Y1124C | Missense Mutation (SNP) | VAF 273/547 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs746839369; called by muse, mutect2, varscan2
- CTTNBP2 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as COSV50469420; called by muse, mutect2, varscan2
- DMD | c.6684G>T p.E2228D | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV100626247; called by muse, mutect2, varscan2
- DNAJC13 | c.6726G>C p.Q2242H | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV53459575; called by muse, mutect2, varscan2
- DSC3 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs367811987; called by muse, mutect2, varscan2
- ERCC4 | c.2266G>T p.V756L | Missense Mutation (SNP) | VAF 89/545 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as rs201501958; called by muse, mutect2, varscan2
- ESRRG | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV63183091; called by muse, varscan2
- EXTL3 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV99594032; called by muse, mutect2, varscan2
- FLG2 | c.2326G>C p.G776R | Missense Mutation (SNP) | VAF 80/591 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV66169752; called by muse, mutect2, varscan2
- FMO3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs774866097, CM078327; called by muse, mutect2, varscan2
- FRMPD2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV59724810; called by muse, mutect2
- FRY | c.2270G>T p.R757L | Missense Mutation (SNP) | VAF 79/417 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66569931; called by muse, mutect2, varscan2
- FUCA1 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs748024437; called by muse, mutect2, varscan2
- FXYD5 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs770639278; called by muse, mutect2
- HK3 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52843464; called by muse, mutect2, varscan2
- IFNGR2 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 86/533 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV51639611; called by muse, mutect2, varscan2
- IGHV1-45 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs1555523785; called by muse, mutect2, varscan2
- ITIH2 | c.1155C>A p.G385= | Splice Region (SNP) | VAF 24/127 reads (19%) | catalogued as COSV64432000; called by muse, mutect2, varscan2
- KCNK2 | c.1043G>T p.S348I (on ENST00000444842 / NM_001017425.3; = p.S333I on NM_014217.4) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67211679; called by muse, varscan2
- KDM4C | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs747747923; called by muse, mutect2, varscan2
- KIF21A | c.1961T>C p.I654T (on ENST00000361418 / NM_001378440.1; = p.I641T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62775818; called by muse, mutect2, varscan2
- KRTAP9-6 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 66/416 reads (16%) | SIFT deleterious (0.01); catalogued as rs750786170; called by muse, mutect2, varscan2
- MRE11 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1386604215; called by muse, mutect2, varscan2
- MROH8 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV54119697, COSV99458096; called by muse, mutect2, varscan2
- MYO18B | c.5401C>T p.R1801W | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980051048, COSV59138727; called by muse, mutect2, varscan2
- NLGN4X | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 66/354 reads (19%) | catalogued as COSV52004086, COSV52005398; called by muse, varscan2
- NLRP3 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60230935; called by muse, mutect2, varscan2
- NOX3 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 70/241 reads (29%) | catalogued as rs1221025923; called by muse, mutect2, varscan2
- NRXN1 | c.4237C>A p.L1413M | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60524852; called by muse, mutect2, varscan2
- OPN5 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs376934583; called by muse, mutect2, varscan2
- OR5J2 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56620223, COSV56620652; called by muse, mutect2, varscan2
- OR6Y1 | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV56930984; called by muse, mutect2, varscan2
- PAPPA2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.992); catalogued as COSV62773124; called by muse, mutect2
- PCDHA11 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56480685; called by muse, mutect2, varscan2
- PCDHB15 | c.1916G>T p.R639M | Missense Mutation (SNP) | VAF 106/557 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV51425088; called by muse, mutect2, varscan2
- PGBD5 | c.896C>T p.A299V (on ENST00000525115; = p.A368V on NM_001258311.2) | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs889200747; called by muse, mutect2, varscan2
- PHLDB3 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52672496; called by muse, mutect2
- PHOSPHO1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs1452718952; called by muse, mutect2, varscan2
- PLPPR4 | c.1983C>A p.Y661* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | catalogued as COSV64567796; called by muse, mutect2, varscan2
- POLQ | c.7642G>A p.E2548K | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs368813941; called by muse, mutect2, varscan2
- PRDM9 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 86/788 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99690637; called by muse, mutect2, varscan2
- R3HDM1 | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs955098598; called by muse, mutect2, varscan2
- RABL6 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs766289000, COSV61039738; called by muse, mutect2, varscan2
- RGL3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62697557; called by muse, mutect2
- RORB | c.468C>G p.H156Q (on ENST00000396204 / NM_001365023.1; = p.H145Q on NM_006914.4) | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1452877829, COSV65340202; called by muse, mutect2
- SCEL | c.1474A>T p.I492F (on ENST00000349847 / NM_144777.3; = p.I472F on NM_003843.4) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV62994533; called by muse, mutect2, varscan2
- SCN10A | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71861955; called by muse, mutect2, varscan2
- SCYL2 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62568044; called by muse, varscan2
- SETD1B | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57350833; called by muse, mutect2, varscan2
- SLC38A8 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs374578326, COSV55307383; called by muse, mutect2
- SLC6A5 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1216195877, COSV54223320; called by mutect2, varscan2
- SLCO1C1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 77/414 reads (19%) | catalogued as COSV56871867, COSV56872540; called by muse, mutect2, varscan2
- SLFN5 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.481); catalogued as COSV55481926; called by muse, mutect2
- SLX4 | c.3056C>T p.S1019F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1427016496, COSV53564094; called by muse, mutect2, varscan2
- SMAD6 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs900897541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA2 | c.3638G>C p.R1213P | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1314729940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.3534G>T p.W1178C | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60786216; called by muse, mutect2, varscan2
- SP140 | c.1415C>A p.T472K | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV59446924; called by muse, mutect2, varscan2
- SPACA1 | c.418C>G p.H140D | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV52759079; called by muse, mutect2, varscan2
- SPDYE1 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 132/613 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1467028396; called by muse, mutect2, varscan2
- SPICE1 | c.2141C>G p.S714C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV55622467; called by muse, mutect2, varscan2
- STEAP1 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1437275150, COSV51881816; called by muse, mutect2
- STYK1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 82/530 reads (15%) | catalogued as COSV50013166; called by muse, mutect2, varscan2
- TBC1D21 | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100311381; called by muse, varscan2
- TBC1D4 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as rs373660487; called by muse, mutect2
- TDP2 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1462495884; called by muse, mutect2
- THEMIS | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1283420042; called by muse, mutect2, varscan2
- TMEFF2 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs369037663; called by muse, mutect2
- TMEM151A | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100516925; called by muse, mutect2, varscan2
- TMEM211 | c.516G>A p.W172* (on ENST00000423535; = p.W101* on NM_001001663.3) | Nonsense Mutation (SNP) | VAF 51/278 reads (18%) | catalogued as COSV66954474; called by muse, mutect2, varscan2
- TYR | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 108/572 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV99634434; called by mutect2, varscan2
- USP29 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs1456583346, COSV54146262; called by muse, mutect2, varscan2
- WDR62 | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 55/481 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs748691163; called by muse, mutect2, varscan2
- WDR72 | c.2248C>G p.L750V | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV100855215; called by muse, mutect2, varscan2
- ZNF541 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs777763555; called by muse, mutect2
- AARSD1 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- ABCA12 | c.1766C>A p.P589H (on ENST00000272895 / NM_173076.3; = p.P271H on NM_015657.3) | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- AC013489.1 | c.497del p.P166Lfs*15 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | called by mutect2, pindel, varscan2
- AKT1S1 | c.142G>T p.A48S (on ENST00000344175 / NM_001098633.4; = p.A68S on NM_032375.5) | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ALAS2 | c.898T>C p.F300L | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ARID1B | c.2897A>T p.Y966F | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ARMC3 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2
- ARSB | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 72/365 reads (20%) | called by muse, mutect2, varscan2
- ASTN1 | c.2617C>A p.P873T | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP11A | c.1727A>T p.K576I | Missense Mutation (SNP) | VAF 68/410 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AXDND1 | c.1842C>G p.F614L | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFC | c.1445C>G p.S482* | Nonsense Mutation (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- BTG4 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BTNL9 | c.584C>A p.P195H | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- C2CD2L | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C3 | c.2746G>C p.V916L | Missense Mutation (SNP) | VAF 100/510 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- C7 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1C | c.4638G>A p.M1546I | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CAGE1 | c.518C>G p.A173G (on ENST00000512086; = p.A37G on NM_205864.3) | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CCDC120 | c.1784A>T p.Y595F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.956); called by muse, varscan2
- CCDC168 | c.9478G>A p.D3160N | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, varscan2
- CCDC74B | c.638A>T p.H213L | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CCL4L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 78/1410 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2
- CENPI | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHEK1 | c.614-1G>A p.X205_splice | Splice Site (SNP) | VAF 15/148 reads (10%) | called by muse, varscan2
- CNST | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CTAG2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CTNNA2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CTTNBP2 | c.2597G>C p.R866T | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CUTC | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- DBN1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DCAF5 | c.2287C>G p.Q763E | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX52 | c.902A>T p.K301M | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, varscan2
- DEF6 | c.1473G>T p.K491N | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- DEF6 | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 94/391 reads (24%) | called by muse, mutect2, varscan2
- DENND2D | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 55/508 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DLC1 | c.925A>T p.K309* | Nonsense Mutation (SNP) | VAF 54/266 reads (20%) | called by muse, mutect2, varscan2
- DMRTB1 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- DOCK10 | c.1018-2A>G p.X340_splice | Splice Site (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2, varscan2
- DPP8 | c.2462+2T>G p.X821_splice (on ENST00000341861 / NM_001320875.2; = p.X705_splice on NM_017743.6) | Splice Site (SNP) | VAF 15/100 reads (15%) | called by mutect2, varscan2
- DUSP5 | c.462del p.R155Efs*12 | Frame Shift Del (DEL) | VAF 53/393 reads (13%) | called by mutect2, pindel, varscan2
- ELMO1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 47/257 reads (18%) | called by muse, mutect2, varscan2
- ERBIN | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- ERCC4 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- F8 | c.4666G>A p.E1556K | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM163A | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 95/423 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FAM187A | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- FBN2 | c.6883C>G p.L2295V | Missense Mutation (SNP) | VAF 34/464 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FBXO3 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FCGBP | c.6643A>T p.N2215Y | Missense Mutation (SNP) | VAF 218/2390 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FCGBP | c.4586-1G>C p.X1529_splice | Splice Site (SNP) | VAF 75/785 reads (10%) | called by muse, mutect2, varscan2
- FGD1 | c.2710del p.E904Rfs*42 | Frame Shift Del (DEL) | VAF 49/377 reads (13%) | called by mutect2, pindel, varscan2
- FLG2 | c.5418C>A p.Y1806* | Nonsense Mutation (SNP) | VAF 73/454 reads (16%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.289+5G>T | Splice Region (SNP) | VAF 24/158 reads (15%) | called by muse, mutect2, varscan2
- FPR3 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GATM | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GDA | c.392C>A p.T131K | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- GLUD1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.238); called by muse, mutect2
- GNAT2 | c.631T>A p.W211R | Missense Mutation (SNP) | VAF 70/438 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR6 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GRM5 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 20/550 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GTF2E2 | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- GTF2I | c.2524G>A p.E842K (on ENST00000573035 / NM_032999.4; = p.E801K on NM_001518.5) | Missense Mutation (SNP) | VAF 90/744 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, varscan2
- GTPBP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.809); called by muse, varscan2
- HBG2 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 120/986 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HCN3 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HECTD4 | c.6473G>A p.G2158E | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- HMGXB3 | c.3521G>C p.W1174S (on ENST00000613459; = p.W928S on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMX3 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by mutect2, varscan2
- HOOK2 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- HOXD8 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HR | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSBP1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- HUWE1 | c.8743G>A p.E2915K | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGBP1P2 | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- IL12RB2 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.039); called by muse, varscan2
- IL1RAPL2 | c.217A>T p.R73W | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IQCC | c.369G>T p.W123C | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ITIH2 | c.2793C>A p.Y931* | Nonsense Mutation (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- KCNK3 | c.551G>T p.W184L | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF1C | c.2067G>T p.W689C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KIF4B | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 58/628 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- KMT2A | c.7736C>T p.S2579L | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT222 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 56/277 reads (20%) | called by muse, mutect2, varscan2
- KRT26 | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- KRTAP11-1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- KRTAP11-1 | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 68/391 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KRTAP9-4 | c.318C>A p.Y106* | Nonsense Mutation (SNP) | VAF 170/740 reads (23%) | called by muse, mutect2, varscan2
- LEPR | c.3092T>C p.I1031T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGR5 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIMD1 | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.9686G>T p.W3229L | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRTM4 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- LY6K | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 61/572 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MAGEH1 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MED10 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 40/576 reads (7%) | called by muse, mutect2
- MEGF10 | c.2156A>G p.H719R | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MFAP1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MFSD9 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MIB2 | c.3028G>T p.V1010L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MMP12 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- MMP12 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MOSMO | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 16/479 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MPL | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- MTRNR2L7 | c.51C>A p.D17E | Missense Mutation (SNP) | VAF 17/135 reads (13%) | PolyPhen possibly damaging (0.631); called by muse, varscan2
- MTRNR2L7 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 19/145 reads (13%) | PolyPhen possibly damaging (0.578); called by muse, varscan2
- MUC16 | c.6256A>T p.T2086S | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MYBL2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- NBPF9 | c.944T>A p.L315Q | Missense Mutation (SNP) | VAF 102/814 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, varscan2
- NCKAP5 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- NCKIPSD | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NID2 | c.3744G>C p.W1248C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIPA2 | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP12 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 85/600 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- NPAP1 | c.1021T>G p.S341A | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NR4A1 | c.1624G>C p.V542L | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NSUN3 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NTRK3 | c.1602G>T p.K534N | Missense Mutation (SNP) | VAF 74/468 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OPCML | c.638T>A p.V213E | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- OR4F15 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4K17 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ORC1 | c.1227G>C p.E409D | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OTOL1 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- OTUD6A | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); called by muse, varscan2
- PCDHA1 | c.239A>C p.Q80P | Missense Mutation (SNP) | VAF 82/512 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PCDHGA6 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 17/377 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.104); called by muse, mutect2
- PCDHGB2 | c.1491G>T p.K497N | Missense Mutation (SNP) | VAF 72/334 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PCNX1 | c.3645A>C p.Q1215H | Missense Mutation (SNP) | VAF 11/308 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PCSK1 | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 94/478 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIEZO2 | c.1641G>T p.M547I | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PIP5KL1 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PITHD1 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, varscan2
- PKP2 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCD1 | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- PLIN4 | c.707G>C p.R236T (on ENST00000301286; = p.R251T on NM_001367868.2) | Missense Mutation (SNP) | VAF 48/355 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, varscan2
- PLSCR2 | c.640G>A p.D214N (on ENST00000497985 / NM_001199978.1; = p.D141N on NM_020359.2) | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.331); called by muse, varscan2
- PNKP | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 159/477 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA5 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- POLR1A | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, varscan2
- PPP2R1B | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 95/467 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PQBP1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 63/421 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDX4 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKN | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 37/597 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.351); called by muse, mutect2
- PSAPL1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PXDN | c.2906C>A p.P969H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PXDNL | c.3993G>T p.M1331I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, varscan2
- RALGAPA1 | c.4451C>G p.S1484C | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); called by muse, mutect2
- RASSF7 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- RBBP5 | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- RELN | c.3050C>T p.T1017I | Missense Mutation (SNP) | VAF 38/662 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); called by muse, mutect2
- RERGL | c.54A>T p.K18N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RIC8B | c.536G>T p.R179M | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ROBO3 | c.3943G>C p.V1315L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 19/401 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SCLT1 | c.1658C>G p.S553* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- SH3GL1 | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SH3TC2 | c.2266C>A p.Q756K | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SHQ1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SLC15A5 | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC25A13 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 115/417 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SLC39A12 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK4 | c.2354A>G p.Q785R | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SMARCA2 | c.4295C>G p.S1432* | Nonsense Mutation (SNP) | VAF 76/486 reads (16%) | called by muse, varscan2
- SPTA1 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ST3GAL5 | c.476G>A p.G159E (on ENST00000377332; = p.G199E on NM_003896.4) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAB2 | c.4295C>A p.T1432K | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STARD9 | c.11920A>T p.R3974* | Nonsense Mutation (SNP) | VAF 75/428 reads (18%) | called by muse, mutect2, varscan2
- STT3A | c.1555-1G>T p.X519_splice | Splice Site (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- SVIL | c.6012C>A p.F2004L (on ENST00000355867 / NM_021738.3; = p.F1578L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- SYCP1 | c.2738T>A p.L913Q | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TBX19 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 59/519 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCERG1L | c.1510A>T p.R504* | Nonsense Mutation (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- TDRKH | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TET1 | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- TMEM211 | c.515G>A p.W172* (on ENST00000423535; = p.W101* on NM_001001663.3) | Nonsense Mutation (SNP) | VAF 50/276 reads (18%) | called by muse, mutect2, varscan2
- TPP2 | c.2378G>T p.W793L | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- TRIOBP | c.6173G>T p.R2058L (on ENST00000644935 / NM_001039141.3; = p.R345L on NM_007032.5) | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TTLL5 | c.2571G>C p.Q857H | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- UBE4B | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- USP9X | c.5936A>T p.H1979L | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTP18 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCAN | c.3907G>T p.G1303* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- XDH | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 80/563 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- XRN2 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2
- ZBTB37 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZC3H4 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZMAT5 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZNF337 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- ZNF34 | c.1539C>G p.S513R | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF343 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- ZNF407 | c.5260G>C p.A1754P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZNF714 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- ABCB5 | c.2526G>T p.L842= (on ENST00000404938 / NM_001163941.2; = p.L397= on NM_178559.6) | Silent (SNP) | VAF 80/864 reads (9%) | catalogued as COSV51706992; called by muse, mutect2
- ACTR5 | c.21G>C p.P7= | Silent (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- ADAM10 | c.816G>T p.V272= | Silent (SNP) | VAF 15/506 reads (3%) | called by muse, mutect2
- ADHFE1 | c.639G>C p.S213= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV52553774; called by muse, mutect2, varscan2
- APOB | c.9456A>G p.L3152= | Silent (SNP) | VAF 51/378 reads (13%) | catalogued as rs1040490924; called by muse, mutect2, varscan2
- ARHGAP4 | c.984C>T p.V328= | Silent (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- BICRA | c.3129G>T p.P1043= | Silent (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- CACNA1F | c.4794G>T p.R1598= | Silent (SNP) | VAF 47/330 reads (14%) | called by muse, mutect2, varscan2
- CLUH | c.645G>A p.L215= (on ENST00000435359; = p.L253= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV70929414; called by muse, mutect2, varscan2
- CNTN5 | c.927G>T p.T309= | Silent (SNP) | VAF 51/282 reads (18%) | catalogued as rs199733775; called by muse, mutect2, varscan2
- CNTN5 | c.3105C>G p.L1035= | Silent (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- COL10A1 | c.51T>C p.H17= | Silent (SNP) | VAF 87/321 reads (27%) | called by muse, mutect2, varscan2
- CRACR2A | c.1383G>T p.G461= | Silent (SNP) | VAF 44/223 reads (20%) | called by muse, mutect2, varscan2
- F5 | c.2229A>C p.S743= | Silent (SNP) | VAF 84/377 reads (22%) | called by muse, mutect2
- FCMR | c.471C>T p.S157= | Silent (SNP) | VAF 44/167 reads (26%) | called by muse, mutect2, varscan2
- FER1L6 | c.1395C>T p.F465= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1240595383; called by muse, mutect2, varscan2
- FIGNL2 | c.1527G>A p.A509= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- FMO1 | c.114G>T p.G38= | Silent (SNP) | VAF 42/198 reads (21%) | called by muse, mutect2, varscan2
- FMO3 | c.667C>A p.R223= | Silent (SNP) | VAF 59/310 reads (19%) | called by muse, mutect2, varscan2
- FMO4 | c.900C>T p.T300= | Silent (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- GIPC3 | c.669G>C p.R223= | Silent (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- GRHL1 | c.978C>T p.S326= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- GRIN2A | c.720G>A p.L240= | Silent (SNP) | VAF 17/349 reads (5%) | catalogued as rs1041367014; called by muse, mutect2
- GUSB | c.1254C>T p.F418= | Silent (SNP) | VAF 49/246 reads (20%) | catalogued as COSV100512513; called by muse, mutect2, varscan2
- HAO1 | c.129A>G p.A43= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2
- HEMK1 | c.201C>T p.I67= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs772989554; called by muse, mutect2
- HS6ST2 | c.726C>T p.F242= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as COSV100897399, COSV63712724; called by muse, mutect2
- HSPA12A | c.591C>T p.V197= | Silent (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.93C>G p.S31= | Silent (SNP) | VAF 80/348 reads (23%) | called by muse, mutect2, varscan2
- JAZF1 | c.12C>T p.I4= | Silent (SNP) | VAF 43/283 reads (15%) | catalogued as rs1226320502, COSV99387428; called by muse, mutect2, varscan2
- KAT14 | c.1161C>T p.P387= | Silent (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- KDR | c.3823A>C p.R1275= | Silent (SNP) | VAF 73/378 reads (19%) | catalogued as COSV55768375; called by muse, mutect2, varscan2
- KIR3DL1 | c.717C>T p.S239= | Silent (SNP) | VAF 36/389 reads (9%) | catalogued as rs201979988, COSV58491231; called by muse, mutect2
- LBR | c.942C>T p.F314= | Silent (SNP) | VAF 58/443 reads (13%) | called by muse, mutect2, varscan2
- LRRC71 | c.1479C>T p.L493= | Silent (SNP) | VAF 37/251 reads (15%) | catalogued as rs772709151, COSV100168858; called by muse, mutect2, varscan2
- LRRTM4 | c.870C>A p.T290= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- MAP3K21 | c.456G>T p.A152= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1159266245; called by muse, mutect2, varscan2
- MBOAT7 | c.1176G>A p.Q392= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs377687729, COSV99824976; called by muse, mutect2, varscan2
- MED12L | c.5889G>T p.L1963= | Silent (SNP) | VAF 102/342 reads (30%) | called by muse, mutect2, varscan2
- METTL21C | c.618C>T p.L206= | Silent (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
- MIA3 | c.465G>A p.E155= | Silent (SNP) | VAF 36/233 reads (15%) | called by muse, mutect2, varscan2
- MMP20 | c.1200C>T p.L400= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- MSH6 | c.1693C>T p.L565= | Silent (SNP) | VAF 80/635 reads (13%) | catalogued as rs1168297520; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.19509C>A p.P6503= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- NAT10 | c.33G>T p.R11= | Silent (SNP) | VAF 59/256 reads (23%) | called by muse, mutect2, varscan2
- NNT | c.1920C>T p.T640= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- NPR1 | c.96G>T p.A32= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV64142331; called by muse, mutect2, varscan2
- NTM | c.321G>T p.V107= | Silent (SNP) | VAF 58/301 reads (19%) | catalogued as COSV100869544; called by muse, mutect2, varscan2
- NXPH1 | c.315G>A p.K105= | Silent (SNP) | VAF 48/402 reads (12%) | catalogued as COSV68314522; called by muse, mutect2, varscan2
- OR1L1 | c.252C>T p.I84= (on ENST00000373686; = p.I34= on NM_001005236.3) | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as rs1440939511, COSV100542118; called by muse, mutect2, varscan2
- OR2AT4 | c.270C>T p.F90= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- OR2T33 | c.393C>T p.P131= | Silent (SNP) | VAF 42/638 reads (7%) | catalogued as COSV58814634; called by muse, mutect2
- OR51B4 | c.666G>A p.V222= | Silent (SNP) | VAF 41/222 reads (18%) | called by muse, mutect2, varscan2
- OR56A5 | c.868C>T p.L290= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV60827957; called by muse, mutect2, varscan2
- OR7G2 | c.315C>T p.N105= | Silent (SNP) | VAF 45/345 reads (13%) | called by muse, varscan2
- PAPPA2 | c.189A>C p.P63= | Silent (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2
- PCCA | c.1146C>T p.L382= | Silent (SNP) | VAF 136/594 reads (23%) | catalogued as COSV100886500; called by muse, mutect2, varscan2
- PCDH19 | c.3213C>T p.L1071= (on ENST00000373034 / NM_001184880.2; = p.L1023= on NM_020766.3) | Silent (SNP) | VAF 29/208 reads (14%) | called by muse, mutect2, varscan2
- PIGQ | c.615C>T p.A205= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- PPP1R3F | c.525C>T p.F175= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as rs782585238, COSV104379282, COSV50018000; called by muse, mutect2
- PRDM13 | c.180G>T p.S60= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100980586, COSV65029971; called by muse, mutect2, varscan2
- PRPF6 | c.1191C>T p.L397= | Silent (SNP) | VAF 93/447 reads (21%) | catalogued as rs551300297, COSV53878966; called by muse, mutect2, varscan2
- RBP3 | c.1993C>A p.R665= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs782074671; called by muse, mutect2
- RNPEP | c.1737C>T p.V579= | Silent (SNP) | VAF 33/307 reads (11%) | catalogued as COSV99821779; called by muse, mutect2, varscan2
- ROBO4 | c.1014G>T p.L338= | Silent (SNP) | VAF 18/100 reads (18%) | called by muse, varscan2
- RP1L1 | c.1464G>A p.Q488= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- RYR1 | c.4437A>G p.Q1479= | Silent (SNP) | VAF 42/268 reads (16%) | called by muse, varscan2
- RYR3 | c.4863G>A p.R1621= | Silent (SNP) | VAF 25/298 reads (8%) | called by muse, mutect2
- SFXN5 | c.897C>T p.F299= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs567169280, COSV55586820; called by muse, mutect2, varscan2
- SGCG | c.597G>A p.R199= | Silent (SNP) | VAF 49/387 reads (13%) | called by muse, mutect2, varscan2
- SGPP1 | c.1039C>T p.L347= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as COSV55976350; called by muse, mutect2, varscan2
- SHROOM3 | c.2355C>T p.V785= | Silent (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- SIGMAR1 | c.249C>T p.F83= | Silent (SNP) | VAF 57/349 reads (16%) | called by muse, mutect2, varscan2
- SKP2 | c.334C>T p.L112= | Silent (SNP) | VAF 49/404 reads (12%) | catalogued as rs779990555; called by muse, mutect2, varscan2
- SLC18A3 | c.217C>A p.R73= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1524T>C p.I508= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- SLC5A6 | c.324G>T p.L108= | Silent (SNP) | VAF 43/252 reads (17%) | called by muse, mutect2, varscan2
- SMYD1 | c.1176G>T p.L392= | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, varscan2
- SNX8 | c.549G>A p.Q183= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- SOAT1 | c.447C>T p.L149= | Silent (SNP) | VAF 37/290 reads (13%) | catalogued as COSV100858986; called by muse, mutect2, varscan2
- ST3GAL4 | c.558C>T p.L186= (on ENST00000392669 / NM_001254758.1; = p.L182= on NM_006278.3) | Silent (SNP) | VAF 46/407 reads (11%) | called by muse, mutect2, varscan2
- STAG3 | c.1416C>T p.G472= | Silent (SNP) | VAF 72/516 reads (14%) | catalogued as rs754933040, COSV57934424; called by muse, mutect2, varscan2
- TIAM1 | c.2772G>A p.V924= | Silent (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- TKTL1 | c.1587G>T p.R529= | Silent (SNP) | VAF 64/341 reads (19%) | called by muse, mutect2, varscan2
- TMEM151A | c.1266G>A p.L422= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- U2AF2 | c.864C>T p.F288= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs759718962, COSV58275203; called by muse, mutect2, varscan2
- UBR5 | c.6600C>T p.F2200= | Silent (SNP) | VAF 33/215 reads (15%) | called by muse, mutect2, varscan2
- VWA8 | c.5280C>T p.I1760= | Silent (SNP) | VAF 33/184 reads (18%) | catalogued as rs2274931; called by muse, mutect2, varscan2
- WDHD1 | c.2571C>T p.F857= | Silent (SNP) | VAF 64/408 reads (16%) | catalogued as rs1221119336; called by muse, mutect2, varscan2
- WDR87 | c.1419G>C p.L473= | Silent (SNP) | VAF 144/474 reads (30%) | called by muse, mutect2, varscan2
- YY1AP1 | c.282G>A p.V94= (on ENST00000295566 / NM_139118.2; = p.V17= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/484 reads (16%) | catalogued as rs1558314112; called by muse, mutect2, varscan2
- ZNF462 | c.390C>A p.V130= | Silent (SNP) | VAF 55/253 reads (22%) | called by muse, mutect2, varscan2
- ZNF736 | c.1248G>A p.K416= | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, varscan2
- ZSWIM4 | c.2046G>A p.L682= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as rs945176565, COSV54321658; called by muse, mutect2, varscan2
- AGBL4 | c.34+28504A>C | Intron (SNP) | VAF 40/279 reads (14%) | called by muse, mutect2, varscan2
- AKR1C8P | c.378+97C>A | Intron (SNP) | VAF 97/402 reads (24%) | called by muse, mutect2, varscan2
- AL353753.1 | n.366del | RNA (DEL) | VAF 20/138 reads (14%) | called by mutect2, pindel, varscan2
- AL772337.1 | n.644G>T | RNA (SNP) | VAF 12/206 reads (6%) | catalogued as rs1182186551; called by muse, mutect2
- ARHGEF10L | c.2172-320G>T | Intron (SNP) | VAF 39/206 reads (19%) | called by muse, mutect2, varscan2
- C2CD3 | c.1843+195A>T | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, varscan2
- C7orf66 | n.245G>C | RNA (SNP) | VAF 20/470 reads (4%) | called by muse, mutect2
- CCNT2 | c.494-202del | Intron (DEL) | VAF 39/260 reads (15%) | catalogued as rs1559108164; called by mutect2, pindel, varscan2
- CFL2 | c.*1238G>A | 3'UTR (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- CYTH4 | c.957+10C>T | Intron (SNP) | VAF 35/259 reads (14%) | called by muse, mutect2, varscan2
- DERA | chr12:15911310 C>A | 5'Flank (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- DRAXIN | c.*2G>T | 3'UTR (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- DYSF | c.3174+22G>T | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- EBNA1BP2 | chr1:43172395 C>T | 5'Flank (SNP) | VAF 25/218 reads (11%) | catalogued as rs957821523; called by muse, mutect2, varscan2
- FAM230J | n.462C>T | RNA (SNP) | VAF 56/827 reads (7%) | called by muse, mutect2
- FRMD8P1 | n.561C>T | RNA (SNP) | VAF 80/272 reads (29%) | called by muse, mutect2, varscan2
- GUSB | c.1066-14C>A | Intron (SNP) | VAF 69/354 reads (19%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.80-38G>T | Intron (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100506534; called by muse, mutect2, varscan2
- IGKV1-12 | c.-17C>A | 5'UTR (SNP) | VAF 74/856 reads (9%) | called by muse, mutect2
- IL21R | c.-4C>T | 5'UTR (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- KIAA1522 | c.235+11975G>T | Intron (SNP) | VAF 34/172 reads (20%) | catalogued as rs1310640889; called by muse, mutect2, varscan2
- MBNL3 | c.1053+796G>C | Intron (SNP) | VAF 26/197 reads (13%) | catalogued as COSV63731318; called by muse, varscan2
- MEIS3 | c.859-63A>T | Intron (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- MICOS13 | c.208-62G>T | Intron (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- MTSS1 | c.1036-924G>A | Intron (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- NAA10 | c.22-31G>C | Intron (SNP) | VAF 52/397 reads (13%) | called by muse, mutect2, varscan2
- NTRK1 | c.1178-30G>A | Intron (SNP) | VAF 22/548 reads (4%) | called by muse, mutect2
- PAX4 | c.*209C>A | 3'UTR (SNP) | VAF 62/174 reads (36%) | catalogued as rs1380712682; called by muse, mutect2, varscan2
- POFUT1 | c.*3126T>A | 3'UTR (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- PRKAG3 | c.-2A>C | 5'UTR (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- PRX | c.*13G>T | 3'UTR (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- PTPN6 | chr12:6964183 G>T | 3'Flank (SNP) | VAF 55/288 reads (19%) | called by muse, mutect2, varscan2
- PTPRR | c.1498-10273G>T | Intron (SNP) | VAF 43/246 reads (17%) | called by muse, mutect2, varscan2
- RPAIN | c.-44C>A | 5'UTR (SNP) | VAF 71/337 reads (21%) | called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570621 G>A | 5'Flank (SNP) | VAF 46/216 reads (21%) | catalogued as rs782570490; called by muse, mutect2, varscan2
- SEMA4B | c.-19C>T | 5'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- SPNS1 | c.*99G>A | 3'UTR (SNP) | VAF 16/116 reads (14%) | catalogued as rs1132052; called by muse, mutect2, varscan2
- ST3GAL3 | c.*26G>A | 3'UTR (SNP) | VAF 66/349 reads (19%) | catalogued as rs1477162591; called by muse, mutect2, varscan2
- SVOPL | c.1354-679G>A | Intron (SNP) | VAF 26/110 reads (24%) | catalogued as rs561695851; called by muse, mutect2, varscan2
- SYT14 | c.*1123G>T | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- TFR2 | c.615-29T>A | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- TMEM52B | c.-4C>A | 5'UTR (SNP) | VAF 61/255 reads (24%) | called by muse, mutect2, varscan2
- TPD52 | c.404+671G>T | Intron (SNP) | VAF 41/169 reads (24%) | called by muse, varscan2
- TPI1 | c.*320C>T | 3'UTR (SNP) | VAF 72/438 reads (16%) | catalogued as rs782187545; called by muse, mutect2, varscan2
- TRPM6 | c.841+14G>T | Intron (SNP) | VAF 82/395 reads (21%) | called by mutect2, varscan2
- TTLL10 | c.-28+1345G>C | Intron (SNP) | VAF 42/348 reads (12%) | called by muse, mutect2, varscan2
- TULP1 | c.-17C>T | 5'UTR (SNP) | VAF 61/249 reads (24%) | called by muse, mutect2, varscan2
- TYMP | c.418-50G>C | Intron (SNP) | VAF 8/172 reads (5%) | catalogued as rs1303360835; called by muse, mutect2
- UGT2B27P | n.273G>C | RNA (SNP) | VAF 40/254 reads (16%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3782T>A | Intron (SNP) | VAF 40/496 reads (8%) | called by muse, mutect2
- WT1 | chr11:32438943 G>T | 5'Flank (SNP) | VAF 68/280 reads (24%) | called by muse, mutect2, varscan2
- ZNF252P | n.1571C>T | RNA (SNP) | VAF 17/284 reads (6%) | called by muse, mutect2
- ZSCAN32 | c.557-18G>C | Intron (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
